MMRF case MMRF_2486 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7a4989cf-0326-4ef2-a394-6bc36f099471

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 34 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 34.9 years (12,764 days); ISS stage: I; Days to last known disease status: 707 days (1.9 years); Days to last follow up: 707 days (1.9 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 176 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 217 days; Days to treatment end: 217 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 219 days; Days to treatment end: 219 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 288 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 337 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 288 days; Days to treatment end: 552 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 295 days; Days to treatment end: 303 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 316 days; Days to treatment end: 331 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 344 days; Days to treatment end: 344 days.
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 383 days (1.0 years); Days to treatment end: 547 days (1.5 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 383 days (1.0 years); Days to treatment end: 553 days (1.5 years).
   Treatment given: Therapeutic agents: Carfilzomib; Regimen or line of therapy: First line of therapy; Days to treatment start: 560 days (1.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 560 days (1.5 years); Days to treatment end: 629 days (1.7 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 714 days (2.0 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day 6 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1190 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.891 mg/dL; Beta 2 Microglobulin 2.1 µg/mL; Lactate Dehydrogenase 3.17 µkat/L; Hemoglobin 6.08 mmol/L; Leukocytes 7.6 ×10⁹/L; Absolute Neutrophil 6.2 ×10⁹/L; Platelets 285 ×10⁹/L; Creatinine 48.6 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.35 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 4.95 mmol/L; C-Reactive Protein 0.18 mg/dL.
- Day 91 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 138 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.943 mg/dL; Hemoglobin 7.81 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 5.25 ×10⁹/L; Platelets 262 ×10⁹/L; Creatinine 40.7 µmol/L; Blood Urea Nitrogen 1.79 mmol/L; Calcium 2.2 mmol/L; Glucose 4.07 mmol/L.
- Day 189 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 66.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.989 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.753 g/L; Immunoglobulin M 0.212 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.7 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 271 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 39 g/L; Total Protein 7.3 g/dL; Glucose 5.17 mmol/L.
- Day 279 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 30.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.9 mg/dL; Immunoglobulin G 19.5 g/L; Immunoglobulin A 3.46 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.7 mmol/L; Leukocytes 9.2 ×10⁹/L; Absolute Neutrophil 5.1 ×10⁹/L; Platelets 168 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 41 g/L; Total Protein 7.9 g/dL; Glucose 5.28 mmol/L.
- Day 370 (ECOG 1): M Protein 0.2 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 24.1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 7.08 mg/dL; Immunoglobulin G 24.5 g/L; Immunoglobulin A 5.35 g/L; Immunoglobulin M 0.813 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 148 ×10⁹/L; Creatinine 64.5 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.23 mmol/L; Albumin 38 g/L; Total Protein 8 g/dL; Glucose 4.51 mmol/L.
- Day 460 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 3.61 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 9.61 g/L; Immunoglobulin A 2.61 g/L; Immunoglobulin M 0.203 g/L; Hemoglobin 6.32 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.3 ×10⁹/L; Platelets 113 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.33 mmol/L; Albumin 38 g/L; Total Protein 7.2 g/dL; Glucose 4.9 mmol/L.
- Day 560 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.17 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.51 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 3 ×10⁹/L; Absolute Neutrophil 1.57 ×10⁹/L; Platelets 110 ×10⁹/L; Creatinine 99 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 41 g/L; Total Protein 7.1 g/dL; Glucose 5.17 mmol/L.
- Day 623 (ECOG 0): Serum Free Immunoglobulin Light Chain, Kappa 6.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.8 mg/dL; Immunoglobulin G 14.9 g/L; Immunoglobulin A 3.29 g/L; Immunoglobulin M 0.244 g/L; Hemoglobin 6.01 mmol/L; Leukocytes 1.6 ×10⁹/L; Absolute Neutrophil 0.51 ×10⁹/L; Platelets 28 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.25 mmol/L; Albumin 35 g/L; Total Protein 7.4 g/dL; Glucose 4.84 mmol/L.
- Day 707 (ECOG 1): Serum Free Immunoglobulin Light Chain, Kappa 4.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.84 mg/dL; Immunoglobulin G 19.8 g/L; Immunoglobulin A 2.73 g/L; Immunoglobulin M 0.254 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.68 ×10⁹/L; Platelets 84 ×10⁹/L; Creatinine 69 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.5 mmol/L; Albumin 43 g/L; Total Protein 8.1 g/dL; Glucose 5.12 mmol/L.

Other clinical attributes
- Day 6: Weight: 136 kg; Height: 180 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_2486_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: 6 days.
- Sample MMRF_2486_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: 6 days.
